Gene-level copy-number profile of tumor specimen TCGA-60-2719-01A from TCGA case TCGA-60-2719, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 83.2 years (30,379 days).
Specimen TCGA-60-2719-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.31f33b68-fe36-4c81-86b8-ee2d11a82ac7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-60-2719-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8f8fe131-9357-455d-ae3f-669cf399dfb3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 255; copy number 2: 18,391; copy number 3: 11,003; copy number 4: 25,215; copy number 5: 129; copy number 6: 1,931; copy number 7: 385; copy number 8: 1,146; copy number 9: 1,265; copy number 10: 1; copy number 11: 46; copy number 12: 9; copy number 13: 26; copy number 16: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-60-2719-01A-01D-0844-01): tumor purity 0.79, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,265 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:137,998,735–138,033,655, 1 gene, copy number 9 (within-gene range 3–9): CLDN18.
- chr3:138,061,990–198,222,513, 1,055 genes, copy number 9 (broad region; genes not listed).
- chr19:19,254,748–23,512,656, 209 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
